Gene-level copy-number profile of tumor specimen C3L-02654-02 from CPTAC case C3L-02654, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 70.6 years (25,783 days).
Specimen C3L-02654-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aeeeb6bd-c86c-4226-98e6-e62a1a87f2f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02654-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/cc630d51-fef7-400f-9e8f-3cd9b41f2daf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 12,563; copy number 2: 32,566; copy number 3: 8,055; copy number 4: 4,404; copy number 5: 109; copy number 6: 48; copy number 7: 154; copy number 8: 36; copy number 9: 99; copy number 10: 33; copy number 11: 21; copy number 12: 5; copy number 13: 10; copy number 14: 11; copy number 17: 18; copy number 22: 24; copy number 23: 8; copy number 25: 1; copy number 26: 3; copy number 27: 79; copy number 29: 5; copy number 31: 19.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:7,891,003–7,896,716, 2 genes: HSPD1P2, DEFB4A.
- chr17:18,432,051–18,551,705, 10 genes (within-gene range 0–2): KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr19:38,108,500–38,186,265, 2 genes (within-gene range 0–4): AC011465.1, AC011479.3.
- chr21:12,999,676–13,906,488, 33 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13.
- chr21:19,893,113–23,490,724, 37 genes: LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.
- chr21:24,840,550–25,381,756, 12 genes: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1.
- chr21:43,053,191–43,107,570, 2 genes: CBS, U2AF1.
- chr21:43,115,334–43,141,092, 2 genes: MRPL51P2, FRGCA.
- chr21:46,690,764–46,691,226, 1 gene: RPL23AP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 683 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,769,083, 17 genes, copy number 9: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P.
- chr1:149,345,661–150,067,701, 36 genes, copy number 8 (within-gene range 4–8): SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P, AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1.
- chr1:150,236,967–151,583,583, 76 genes, copy number 9 (broad region; genes not listed).
- chr1:157,513,377–157,700,769, 5 genes, copy number 7 (within-gene range 4–7): FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3.
- chr4:46,993,723–47,914,667, 13 genes, copy number 5 (within-gene range 2–5): GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1.
- chr5:191,495–1,345,099, 45 genes, copy number 6: LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:16,473,038–23,689,386, 95 genes, copy number 5–11 (within-gene range 5–13) (broad region; genes not listed).
- chr5:25,909,503–26,749,997, 8 genes, copy number 5–7: MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1.
- chr7:33,014,114–33,877,180, 9 genes, copy number 7 (within-gene range 4–7): NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:40,135,005–40,860,763, 1 gene, copy number 5 (within-gene range 3–5): SUGCT.
- chr7:40,538,127–57,020,273, 276 genes, copy number 5–31 (broad region; genes not listed).
- chr7:63,011,463–63,211,822, 8 genes, copy number 23: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1.
- chr7:63,556,598–63,636,617, 4 genes, copy number 7: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr7:65,084,103–65,100,232, 1 gene, copy number 7: GTF2IP14.
- chr7:65,773,620–65,814,775, 2 genes, copy number 12: GTF2IP5, RNU6-912P.
- chr17:46,372,855–46,509,339, 2 genes, copy number 5–12: NSFP1, RDM1P2.
- chr18:11,552,366–12,040,300, 22 genes, copy number 5: AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1.
- chr19:27,638,483–30,228,715, 58 genes, copy number 5 (within-gene range 4–5): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr20:64,255,695–64,327,972, 5 genes, copy number 5: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 12,563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
